Somatic mutation profile of tumor specimen TCGA-XU-A92V-01A (aliquot TCGA-XU-A92V-01A-11D-A423-09) from TCGA case TCGA-XU-A92V, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 73.0 years (26,646 days).
Specimen TCGA-XU-A92V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fded62dd-7e09-4b74-b378-62915ca97f05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A92V-10A (Blood Derived Normal), aliquot TCGA-XU-A92V-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12b1c73d-caa0-4f2b-b25a-49ece76522c1

The open-access MAF lists 29 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 24, Silent 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 106/418 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- ARHGEF40 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs752058684; called by muse, mutect2, varscan2
- COBL | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.053); catalogued as rs747167571; called by muse, mutect2, varscan2
- CSF2RB | c.2395C>T p.R799C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs544020050, COSV53261337; called by muse, mutect2, varscan2
- DGKI | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.691); catalogued as rs148415050; called by muse, mutect2, varscan2
- HJURP | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs975669293; called by muse, mutect2, varscan2
- HJURP | c.849C>G p.I283M | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263222738; called by muse, mutect2, varscan2
- HJURP | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1348029070; called by muse, mutect2, varscan2
- HLA-DMA | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1455744592; called by muse, mutect2, varscan2
- N4BP1 | c.1669A>G p.N557D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs752155881; called by muse, mutect2, varscan2
- ONECUT3 | c.1175C>A p.S392* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV101210708; called by muse, mutect2, varscan2
- OPRD1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as rs1160699595, COSV99330184; called by muse, mutect2, varscan2
- PMEPA1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55695611; called by muse, mutect2, varscan2
- PPARGC1A | c.1802A>G p.Y601C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1443644914; called by muse, mutect2, varscan2
- SLITRK1 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.379); catalogued as COSV65676982; called by muse, mutect2, varscan2
- ACACB | c.2678A>C p.D893A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- ADGRG4 | c.2462G>A p.G821D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC142 | c.1181T>G p.L394R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMBT1 | c.6241G>T p.D2081Y (on ENST00000338354 / NM_001377530.1; = p.D1324Y on NM_004406.3) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FIGN | c.2207T>A p.I736N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- HJURP | c.1181C>G p.A394G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PJA1 | c.1884G>T p.K628N (on ENST00000361478 / NM_145119.4; = p.K440N on NM_022368.5) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRR13 | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RFX6 | c.1770G>C p.K590N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2
- SARDH | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UTRN | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- FCAR | c.300C>T p.C100= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- MPLKIP | c.210C>T p.G70= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs766916180; called by muse, varscan2
- NLRP5 | c.1932C>T p.D644= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs776601668, COSV101173547, COSV66762842; called by muse, mutect2, varscan2
